Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7608, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7608-01A (Primary Tumor).

Microscopic

Sections demonstrate a mildly to moderately hypercellular glial neoplasm that diffusely infiltrates the gray and white matter. The tumor cells have monotonous round to oval nuclei with little atypical. Cytoplasm is prominent and is often fibrillary that does demonstrate some microgemistocytic and a few ordinary gemistocytic forms. Two mitoses are identified in 25 high power fields. There is no microvascular proliferation or necrosis.

Addendum

Sections demonstrate cortical gray and white matter. The white matter is mildly hypercellular due to an infiltrate of tumor cells that have round, mildly enlarged round nuclei, often with a small nucleolus. Most have obvious perinuclear halos. No mitotic figures are seen. In contrast to the patient's other material which demonstrated a typical astrocytoma phenotype, this material has a classic oligodendroglioma phenotype. Taken together, the findings warrant classification as an oligoastrocytoma.

Scattered MIB-1 reactive cells are present with a labeling index of 1.7%. This is indicative of a minimally proliferative neoplasm and is similar to that reported on the patient's previous biopsy.

Diagnosis

Oligoastrocytoma, low grade

Source: NCI Genomic Data Commons file a53e2e9e-5a6d-4cd4-abb5-f967c6f65542 (TCGA-HT-7608.3E9306B1-C5BC-48E4-9BC2-CD928AEF0584.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).